Gene-level copy-number profile of tumor specimen TCGA-DX-A48N-01A from TCGA case TCGA-DX-A48N, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 47.5 years (17,364 days).
Specimen TCGA-DX-A48N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.dced15f4-6936-4bd2-8c04-9919768b40ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A48N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/742dee72-e28e-4f4a-99cc-40e572c9e15e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 14; copy number 2: 6,138; copy number 3: 1,617; copy number 4: 42,875; copy number 5: 2,795; copy number 6: 2,649; copy number 7: 300; copy number 8: 423; copy number 9: 843; copy number 10: 210; copy number 11: 400; copy number 12: 91; copy number 13: 262; copy number 14: 128; copy number 15: 35; copy number 16: 130; copy number 17: 12; copy number 18: 197; copy number 19: 22; copy number 20: 199; copy number 21: 12; copy number 22: 2; copy number 23: 9; copy number 24: 13; copy number 25: 126; copy number 26: 10; copy number 27: 21; copy number 29: 16; copy number 30: 28; copy number 32: 11; copy number 34: 61; copy number 35: 11; copy number 38: 8; copy number 39: 39; copy number 40: 3; copy number 42: 32; copy number 48: 8; copy number 50: 3; copy number 52: 37; copy number 61: 4; copy number 63: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A48N-01A-11D-A306-01): tumor purity 0.82, ploidy 4.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,001 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–149,048,286, 195 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr1:150,926,263–154,678,345, 226 genes, copy number 11 (broad region; genes not listed).
- chr1:169,662,007–169,854,080, 1 gene, copy number 11 (within-gene range 2–11): C1orf112.
- chr1:169,722,640–171,345,307, 39 genes, copy number 11–19 (within-gene range 2–19): SELE, AL021940.1, METTL18, SCYL3, RN7SL333P, AL031297.1, KIFAP3, RN7SL269P, MRPS10P1, AL356475.1, SIGLEC30P, METTL11B, MIR3119-2, MIR3119-1, LINC01681, ISCUP1, LINC01142, HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4.
- chr1:171,444,699–172,444,086, 23 genes, copy number 11–38 (within-gene range 2–38): CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC.
- chr1:173,417,793–182,560,599, 168 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr1:183,248,237–183,418,380, 1 gene, copy number 42 (within-gene range 6–42): NMNAT2.
- chr1:183,372,870–188,242,678, 77 genes, copy number 34–42 (broad region; genes not listed).
- chr1:190,478,551–191,228,467, 10 genes, copy number 9: LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680.
- chr1:191,858,707–191,890,229, 1 gene, copy number 9: AL359081.1.
- chr3:81,359,739–84,947,061, 19 genes, copy number 9: AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2.
- chr4:38,366,914–41,882,955, 85 genes, copy number 13–24 (within-gene range 4–24) (broad region; genes not listed).
- chr6:132,296,055–152,637,801, 351 genes, copy number 16–25 (within-gene range 4–25) (broad region; genes not listed).
- chr8:102,125,432–102,412,759, 7 genes, copy number 10 (within-gene range 5–10): MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1.
- chr8:106,980,967–107,506,416, 6 genes, copy number 9: AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1.
- chr8:109,086,585–118,982,875, 71 genes, copy number 9–13 (broad region; genes not listed).
- chr9:68,536,580–77,648,322, 114 genes, copy number 20–39 (within-gene range 4–39) (broad region; genes not listed).
- chr9:82,405,188–85,027,054, 36 genes, copy number 15–18: AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1, RN7SKP242, AL137847.3, AL137847.1, FRMD3, AL137847.2, RNU4-29P, RNU4-15P, IDNK, UBQLN1, AL354920.1, GKAP1, AL354733.1, AL354733.2, KIF27, C9orf64, HNRNPK, MIR7-1, AL354733.3, RMI1, Y_RNA, AL390838.1, AL390838.2, SLC28A3, AL356134.1, AL157886.1, AL354692.1, NTRK2.
- chr9:102,256,604–102,657,514, 5 genes, copy number 21: RNU6-329P, AL442644.2, AL442644.1, LINC00587, ZYG11AP1.
- chr12:4,909,867–5,026,012, 1 gene, copy number 12 (within-gene range 1–12): AC005906.2.
- chr12:4,960,113–5,946,232, 12 genes, copy number 12 (within-gene range 3–12): AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3, ANO2, AC137627.1.
- chr12:29,500,840–29,784,759, 1 gene, copy number 17 (within-gene range 6–17): TMTC1.
- chr12:29,658,376–30,321,617, 8 genes, copy number 17: RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1.
- chr12:57,610,180–58,395,138, 38 genes, copy number 10–52 (within-gene range 4–52): ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:67,929,235–68,332,381, 10 genes, copy number 35 (within-gene range 4–35): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1.
- chr12:68,746,125–71,032,083, 47 genes, copy number 20–52 (within-gene range 4–52): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1.
- chr12:74,292,324–74,545,430, 3 genes, copy number 40: VENTXP3, ATXN7L3B, AC025257.1.
- chr12:77,219,603–78,808,995, 12 genes, copy number 20–48 (within-gene range 4–48): LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2.
- chr12:80,707,634–80,770,717, 3 genes, copy number 50: MYF6, MYF5, LINC01490.
- chr12:81,953,719–83,134,870, 11 genes, copy number 32 (within-gene range 4–32): LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P.
- chr12:83,661,009–84,294,562, 4 genes, copy number 17–35: AC093025.1, AC090679.3, AC090679.2, AC090679.1.
- chr12:89,519,408–89,548,005, 4 genes, copy number 18: POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2.
- chr12:92,247,697–92,772,455, 7 genes, copy number 15–20: LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7.
- chr12:97,155,234–100,027,540, 43 genes, copy number 13–27: AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6, AC018659.2, PAFAH1B2P2, RNU6-36P, MIR4495, MIR4303, AC016152.1, AC008055.1, RNU4-41P, AC008055.2, SLC9A7P1, LINC02453, TMPO-AS1, TMPO, PPIAP8, SLC25A3, SNORA53, IKBIP, APAF1, ANKS1B, AC008126.1, AC069437.1, RNA5SP366, AC117377.1, FAM71C, AC078916.1, RPS4XP1, AC126474.1.
- chr12:104,117,086–105,107,643, 18 genes, copy number 63 (within-gene range 8–63): NFYB, RNA5SP370, LINC02385, AC089983.2, TXNRD1, AC089983.1, RPL18AP3, EID3, CHST11, AC079316.1, AC079316.2, MIR3922, SLC41A2, Y_RNA, AC089985.1, KRT18P20, C12orf45, ALDH1L2.
- chr12:106,063,340–130,716,281, 620 genes, copy number 9–61 (within-gene range 8–61) (broad region; genes not listed).
- chr19:6,729,914–15,662,825, 495 genes, copy number 11–18 (broad region; genes not listed).
- chr19:21,358,930–23,687,220, 110 genes, copy number 13–16 (within-gene range 4–16) (broad region; genes not listed).
- chr19:29,606,283–30,085,893, 16 genes, copy number 19: POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr20:62,302,093–63,891,545, 98 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
